Somatic mutation profile of tumor specimen BA3248D (aliquot aq-BA3248D) from BEATAML1.0 case 2663, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.7 years (22,909 days).
Specimen BA3248D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92f10710-246e-4ab1-a438-12d5cccb57d0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3193D (Solid Tissue Normal), aliquot aq-BA3193D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96c202d8-8f09-426f-82ce-14b8106f7d3f

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL1 | c.2075C>T p.T692M | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs1332380683; called by muse, mutect2, varscan2
- LRP1 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.563); catalogued as rs139574269; called by muse, mutect2, varscan2
- BRCC3 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ABL1 | c.2700G>A p.P900= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as rs762520958; called by muse, mutect2, varscan2
- ABL1 | c.2856A>G p.G952= | Silent (SNP) | VAF 86/219 reads (39%) | called by muse, varscan2
- ZNF467 | c.711G>A p.T237= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1436500883; called by muse, mutect2
